Somatic mutation profile of tumor specimen TCGA-AO-A0JF-01A (aliquot TCGA-AO-A0JF-01A-11W-A071-09) from TCGA case TCGA-AO-A0JF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 68.2 years (24,923 days).
Specimen TCGA-AO-A0JF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78071d91-9c63-4a2a-881c-cc32be59dde6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AO-A0JF-10A (Blood Derived Normal), aliquot TCGA-AO-A0JF-10A-01W-A071-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/446fe7f6-9750-4bb7-9a63-60fd79d820e9

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 12, Silent 7, Frame Shift Del 2, Splice Region 2, In Frame Ins 1, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1357G>A p.E453K | Missense Mutation (SNP) | VAF 36/168 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen possibly damaging (0.655); catalogued as rs1057519925, COSV55873816, COSV55874585; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 19/81 reads (23%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- CABIN1 | c.2913G>A p.V971= | Splice Region (SNP) | VAF 28/160 reads (18%) | catalogued as rs767289015, COSV54083592; called by muse, mutect2, varscan2
- EDN1 | c.557T>A p.V186D | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV65080886; called by muse, mutect2, varscan2
- EPHX1 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55301636; called by muse, mutect2, varscan2
- ETS2 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62873276; called by muse, mutect2, varscan2
- HAL | c.971G>C p.S324T | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV54118479, COSV54118562; called by muse, mutect2, varscan2
- HIVEP2 | c.6290G>T p.R2097I | Missense Mutation (SNP) | VAF 9/248 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV50024935, COSV99173376; called by muse, mutect2
- INTS13 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as COSV53903240; called by muse, mutect2, varscan2
- KMT2C | c.1897del p.E633Kfs*2 | Frame Shift Del (DEL) | VAF 33/191 reads (17%) | catalogued as COSV51452776; called by mutect2, pindel, varscan2
- MAP2K4 | c.1153C>G p.L385V | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV62258211; called by muse, mutect2, varscan2
- MAP3K1 | c.4257G>A p.E1419= | Splice Region (SNP) | VAF 57/312 reads (18%) | catalogued as COSV68124459; called by muse, mutect2, varscan2
- PEX2 | c.904G>A p.V302I | Missense Mutation (SNP) | VAF 60/345 reads (17%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.084); catalogued as COSV63813771; called by muse, mutect2, varscan2
- TROAP | c.1396G>A p.V466I | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.14); catalogued as COSV99226831; called by muse, mutect2
- ZNF292 | c.4532A>G p.H1511R | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs1333002273, COSV60541002; called by muse, mutect2, varscan2
- DYDC2 | c.293_298del p.S98_K100delins* | Nonsense Mutation (DEL) | VAF 66/428 reads (15%) | called by mutect2, pindel, varscan2
- MAGED2 | c.1377dup p.A460Cfs*29 | Frame Shift Ins (INS) | VAF 16/86 reads (19%) | called by mutect2, pindel, varscan2
- MAP3K1 | c.1061del p.F354Sfs*8 | Frame Shift Del (DEL) | VAF 10/98 reads (10%) | called by mutect2, pindel, varscan2
- RNF14 | c.861_862insGGA p.L287_F288insG | In Frame Ins (INS) | VAF 17/109 reads (16%) | called by mutect2, pindel, varscan2
- ABCF2 | c.507G>A p.R169= | Silent (SNP) | VAF 23/127 reads (18%) | catalogued as COSV55183824; called by muse, mutect2, varscan2
- FAM136A | c.399C>T p.L133= | Silent (SNP) | VAF 25/109 reads (23%) | catalogued as rs200723862, COSV50682711, COSV50683015; called by muse, mutect2, varscan2
- NECAB1 | c.924T>C p.S308= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs374245319; called by muse, mutect2, varscan2
- PKHD1 | c.310C>T p.L104= | Silent (SNP) | VAF 33/174 reads (19%) | catalogued as COSV61881335; called by muse, mutect2, varscan2
- TCHH | c.3117G>A p.E1039= | Silent (SNP) | VAF 62/515 reads (12%) | catalogued as rs775883612, COSV100915038; called by muse, mutect2, varscan2
- TNS4 | c.1168C>A p.R390= | Silent (SNP) | VAF 21/102 reads (21%) | catalogued as COSV54185743; called by muse, varscan2
- ZNF692 | c.252G>A p.V84= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as COSV60659636; called by muse, mutect2, varscan2
